Somatic mutation profile of tumor specimen 0DIOKN from CCDI case PBBVXS, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 7.5 years (2,724 days).
Specimen 0DIOKN: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ea906ce8-fc50-47e2-8a74-05d90127e0af.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DIOK2 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/021d6f3e-c970-4fc5-bb3b-4306819a21ae

The open-access MAF lists 207 somatic variants for this specimen: 124 protein-altering or splice-affecting, 43 silent, 40 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 105, Silent 43, Intron 30, Nonsense Mutation 9, Frame Shift Del 5, 5'UTR 4, 3'UTR 3, Frame Shift Ins 2, Splice Region 2, RNA 2, Splice Site 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CENPF | c.9280C>T p.R3094* | Nonsense Mutation (SNP) | VAF 30/748 reads (4%) | catalogued as rs869312748, CM162211, COSV65276590; ClinVar: pathogenic; called by muse, mutect2
- HNF1B | c.1561del p.Q521Sfs*70 | Frame Shift Del (DEL) | VAF 179/314 reads (57%) | catalogued as rs764042837; ClinVar: likely pathogenic; called by mutect2, varscan2
- PTEN | c.697C>T p.R233* | Nonsense Mutation (SNP) | VAF 428/715 reads (60%) | hotspot (GDC flag); catalogued as rs121909219, CM971277, COSV64288653, COSV64291717, COSV64302607, COSV64306399, COSV64306519, COSV64311585, COSV99058021; ClinVar: pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.637C>T p.R213* | Nonsense Mutation (SNP) | VAF 236/403 reads (59%) | hotspot (GDC flag); catalogued as rs397516436, CM951226, COSV52665560, COSV52740638, COSV52746781, COSV52782151; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACER2 | c.235G>A p.V79I | Missense Mutation (SNP) | VAF 38/510 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.269); catalogued as rs770384271, COSV61820954; called by muse, mutect2
- ADPRHL1 | c.3917G>A p.R1306H | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.104); catalogued as rs573677872; called by muse, mutect2, varscan2
- ANKRD6 | c.169G>A p.V57M | Missense Mutation (SNP) | VAF 29/1017 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1326463830; called by muse, mutect2
- APEH | c.53G>T p.R18L | Missense Mutation (SNP) | VAF 116/211 reads (55%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.54); catalogued as COSV56529563; called by muse, mutect2, varscan2
- ASIC3 | c.358G>A p.A120T | Missense Mutation (SNP) | VAF 89/235 reads (38%) | SIFT tolerated (0.53); PolyPhen benign (0.003); catalogued as rs370369500; called by muse, mutect2, varscan2
- ASXL2 | c.1841G>A p.R614Q | Missense Mutation (SNP) | VAF 179/378 reads (47%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.946); catalogued as rs1307171996; called by muse, mutect2, varscan2
- BAHCC1 | c.3572C>T p.A1191V | Missense Mutation (SNP) | VAF 69/96 reads (72%) | SIFT tolerated (0.07); PolyPhen benign (0.031); catalogued as rs549555237, COSV57023720; called by muse, mutect2, varscan2
- CABP4 | c.409G>A p.A137T | Missense Mutation (SNP) | VAF 211/482 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs770118394, COSV56885910; called by muse, mutect2, varscan2
- CARD6 | c.271G>A p.G91S | Missense Mutation (SNP) | VAF 170/480 reads (35%) | SIFT tolerated (0.33); PolyPhen benign (0.136); catalogued as rs745413137, COSV54569275; called by muse, mutect2, varscan2
- CHAD | c.520C>T p.R174C | Missense Mutation (SNP) | VAF 223/369 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs146207513; called by muse, mutect2, varscan2
- CHML | c.628G>A p.D210N | Missense Mutation (SNP) | VAF 243/417 reads (58%) | SIFT tolerated (0.31); PolyPhen benign (0.015); catalogued as rs780533014, COSV100087029; called by muse, mutect2, varscan2
- CLIC5 | c.802C>T p.R268W (on ENST00000185206 / NM_001370649.1; = p.R109W on NM_016929.5) | Missense Mutation (SNP) | VAF 387/638 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs771084229, COSV51757733, COSV99483445; called by muse, mutect2, varscan2
- COL1A2 | c.727G>A p.V243M | Missense Mutation (SNP) | VAF 303/845 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.288); catalogued as rs764373659, COSV99800278; called by muse, mutect2, varscan2
- CRY2 | c.823C>T p.R275C | Missense Mutation (SNP) | VAF 392/613 reads (64%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs368725163; called by muse, mutect2, varscan2
- CXorf65 | c.476C>T p.P159L | Missense Mutation (SNP) | VAF 360/653 reads (55%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs757926405; called by muse, mutect2, varscan2
- CYP2A7 | c.1072G>A p.E358K | Missense Mutation (SNP) | VAF 228/484 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs754736886; called by muse, mutect2, varscan2
- CYP4F12 | c.1549G>A p.E517K | Missense Mutation (SNP) | VAF 220/400 reads (55%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.909); catalogued as COSV61172905; called by muse, mutect2, varscan2
- DHX58 | c.1807G>A p.D603N | Missense Mutation (SNP) | VAF 327/579 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782702878, COSV52424795; called by muse, mutect2, varscan2
- DNAH8 | c.11045G>A p.R3682Q | Missense Mutation (SNP) | VAF 46/532 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1180817252; called by muse, mutect2
- EEF1AKNMT | c.2084C>T p.T695M (on ENST00000361735 / NM_015935.5; = p.T609M on NM_014955.3) | Missense Mutation (SNP) | VAF 27/363 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs575314244, COSV62283000; called by muse, mutect2
- EFNB2 | c.545G>A p.R182H | Missense Mutation (SNP) | VAF 99/1179 reads (8%) | SIFT tolerated (0.55); PolyPhen benign (0.026); catalogued as rs777601389, COSV99808537; called by muse, mutect2
- EPHA5 | c.2468G>A p.R823Q | Missense Mutation (SNP) | VAF 65/770 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs1345783479, COSV56630047; called by muse, mutect2
- FAM107A | c.76C>T p.R26* | Nonsense Mutation (SNP) | VAF 214/345 reads (62%) | catalogued as rs766366211; called by muse, mutect2, varscan2
- FAM222B | c.994G>A p.A332T | Missense Mutation (SNP) | VAF 177/256 reads (69%) | SIFT tolerated (0.34); PolyPhen benign (0.085); catalogued as rs761764271; called by muse, mutect2, varscan2
- FBXW4 | c.1564C>T p.R522C | Missense Mutation (SNP) | VAF 288/511 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1418569736, COSV100489341; called by muse, mutect2, varscan2
- FCGBP | c.10960C>T p.R3654C | Missense Mutation (SNP) | VAF 56/108 reads (52%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.804); catalogued as rs1336782101; called by muse, mutect2, varscan2
- FER | c.940G>A p.E314K | Missense Mutation (SNP) | VAF 52/876 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs372482792; called by muse, mutect2
- FER1L6 | c.2206G>A p.A736T | Missense Mutation (SNP) | VAF 371/614 reads (60%) | SIFT deleterious (0.03); PolyPhen benign (0.007); catalogued as rs376154841; called by muse, mutect2, varscan2
- GALNT10 | c.487C>T p.R163C | Missense Mutation (SNP) | VAF 400/624 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs934984053; called by muse, mutect2, varscan2
- GAR1 | c.562G>A p.G188S | Missense Mutation (SNP) | VAF 170/408 reads (42%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.672); catalogued as rs1405416414; called by muse, mutect2, varscan2
- GBF1 | c.3638G>A p.R1213Q (on ENST00000369983 / NM_001377137.1; = p.R1212Q on NM_004193.3) | Missense Mutation (SNP) | VAF 404/653 reads (62%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs776641967; called by muse, mutect2, varscan2
- GDPD5 | c.1255G>A p.A419T | Missense Mutation (SNP) | VAF 228/393 reads (58%) | SIFT tolerated (0.18); PolyPhen benign (0); catalogued as rs142603773; called by muse, mutect2, varscan2
- HOXA10 | c.1010G>A p.R337Q | Missense Mutation (SNP) | VAF 54/1414 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52230629; called by muse, mutect2
- IGLON5 | c.232C>T p.R78C | Missense Mutation (SNP) | VAF 154/265 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs1002853568, COSV54537855; called by muse, mutect2, varscan2
- IL12B | c.511G>A p.G171R | Missense Mutation (SNP) | VAF 238/422 reads (56%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.766); catalogued as rs189313574, COSV104370859; called by muse, mutect2, varscan2
- IRAK1 | c.590C>T p.P197L | Missense Mutation (SNP) | VAF 314/433 reads (73%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.747); catalogued as rs1557130371, COSV57653308; called by muse, mutect2, varscan2
- ITIH5 | c.2518G>A p.G840R | Missense Mutation (SNP) | VAF 287/500 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779097410, COSV53670538; called by muse, mutect2, varscan2
- LMO7 | c.3902G>A p.R1301Q (on ENST00000357063; = p.R982Q on NM_005358.5) | Missense Mutation (SNP) | VAF 89/692 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.261); catalogued as rs775620229, COSV58545592; called by muse, mutect2, varscan2
- LYG1 | c.554G>A p.R185Q | Missense Mutation (SNP) | VAF 203/426 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.049); catalogued as rs779624939; called by muse, mutect2, varscan2
- MED13L | c.6523G>A p.A2175T | Missense Mutation (SNP) | VAF 295/813 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1332477505; called by muse, mutect2, varscan2
- MGAT4C | c.202C>T p.R68C | Missense Mutation (SNP) | VAF 324/869 reads (37%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.659); catalogued as rs762956258; called by muse, mutect2, varscan2
- MYO15B | c.6179C>T p.T2060M | Missense Mutation (SNP) | VAF 181/336 reads (54%) | SIFT tolerated (0.36); PolyPhen benign (0.242); catalogued as rs375540119, COSV101640080; called by muse, varscan2
- NUP210L | c.740G>A p.R247H | Missense Mutation (SNP) | VAF 239/380 reads (63%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs77184519; called by muse, mutect2, varscan2
- OCA2 | c.70G>A p.V24M | Missense Mutation (SNP) | VAF 44/497 reads (9%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.143); catalogued as rs766829294; called by muse, mutect2
- ODF2 | c.2467C>T p.R823C (on ENST00000434106 / NM_153433.2; = p.R799C on NM_002540.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 231/371 reads (62%) | SIFT deleterious (0.02); PolyPhen benign (0.055); catalogued as rs368885613; called by muse, mutect2, varscan2
- OPRD1 | c.847G>A p.V283I | Missense Mutation (SNP) | VAF 25/458 reads (5%) | SIFT tolerated (0.26); PolyPhen benign (0.153); catalogued as rs1324003441; called by muse, mutect2
- PCDHA8 | c.1444G>A p.A482T | Missense Mutation (SNP) | VAF 286/458 reads (62%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.231); catalogued as COSV65336607; called by muse, mutect2, varscan2
- PCDHB10 | c.691G>A p.V231I | Missense Mutation (SNP) | VAF 28/365 reads (8%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.327); catalogued as rs782159443, COSV53379375; called by muse, mutect2
- PCDHB12 | c.1348G>A p.A450T | Missense Mutation (SNP) | VAF 170/396 reads (43%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.005); catalogued as rs782357019; called by muse, mutect2, varscan2
- PFKFB4 | c.347G>A p.R116Q | Missense Mutation (SNP) | VAF 348/591 reads (59%) | PolyPhen benign (0.003); catalogued as rs745957312; called by muse, mutect2, varscan2
- PLCB3 | c.3409C>T p.R1137C | Missense Mutation (SNP) | VAF 102/213 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1254014643; called by muse, mutect2, varscan2
- POLE | c.6338C>A p.S2113Y | Missense Mutation (SNP) | VAF 74/363 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV57674618; called by muse, mutect2, varscan2
- PPP6R2 | c.1571C>T p.T524M | Missense Mutation (SNP) | VAF 180/334 reads (54%) | SIFT tolerated (0.08); PolyPhen benign (0.179); catalogued as rs377314097; called by muse, mutect2, varscan2
- PRSS53 | c.605C>T p.P202L | Missense Mutation (SNP) | VAF 201/331 reads (61%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs755835778, COSV54923478; called by muse, varscan2
- PSAP | c.1198G>A p.V400M | Missense Mutation (SNP) | VAF 170/372 reads (46%) | SIFT tolerated (0.18); PolyPhen benign (0.107); catalogued as rs1210917733, COSV56486779; called by muse, mutect2, varscan2
- RAPSN | c.902C>T p.A301V | Missense Mutation (SNP) | VAF 27/334 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs778113748, COSV100100331; called by muse, mutect2
- RB1 | c.2206C>T p.Q736* | Nonsense Mutation (SNP) | VAF 302/517 reads (58%) | catalogued as CM1312467, COSV57305995; called by muse, mutect2, varscan2
- RDH12 | c.679G>A p.A227T | Missense Mutation (SNP) | VAF 180/413 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.136); catalogued as COSV50822737; called by muse, mutect2, varscan2
- RECQL | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 189/764 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.038); catalogued as rs566339459, COSV57553564; called by muse, mutect2, varscan2
- RGS12 | c.29G>A p.R10H | Missense Mutation (SNP) | VAF 176/302 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs1202694533, COSV100376251; called by muse, mutect2, varscan2
- SAFB | c.2131C>T p.R711W | Missense Mutation (SNP) | VAF 13/284 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.609); catalogued as rs1376517954; called by muse, mutect2
- SCN5A | c.101G>A p.R34H | Missense Mutation (SNP) | VAF 228/387 reads (59%) | SIFT deleterious (0.03); PolyPhen benign (0.253); catalogued as rs199473046, COSV100028541; ClinVar: uncertain significance / not provided; called by muse, mutect2, varscan2
- SCUBE3 | c.1609C>T p.R537* | Nonsense Mutation (SNP) | VAF 195/411 reads (47%) | catalogued as rs772093718; called by muse, mutect2, varscan2
- SLC17A1 | c.1397G>A p.R466H | Missense Mutation (SNP) | VAF 43/776 reads (6%) | SIFT tolerated (0.34); PolyPhen benign (0.062); catalogued as rs139792251, COSV55077092; called by muse, mutect2
- SLC28A2 | c.139G>T p.G47W | Missense Mutation (SNP) | VAF 28/520 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0.379); catalogued as rs1454012621; called by muse, mutect2
- SLC39A6 | c.1132C>T p.L378F | Missense Mutation (SNP) | VAF 166/552 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs1238492417, COSV52369929; called by muse, mutect2, varscan2
- SLC7A2 | c.1592C>T p.A531V (on ENST00000494857 / NM_001370338.1; = p.A570V on NM_003046.6) | Missense Mutation (SNP) | VAF 50/706 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs772998799, COSV50262885; called by muse, mutect2
- SLIT1 | c.1756G>A p.E586K | Missense Mutation (SNP) | VAF 390/608 reads (64%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.551); catalogued as rs779976459; called by muse, mutect2, varscan2
- SMARCA2 | c.4480G>A p.V1494I | Missense Mutation (SNP) | VAF 417/708 reads (59%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.874); catalogued as rs1307331797, COSV56647692; called by muse, mutect2, varscan2
- SMARCA4 | c.2176C>T p.R726C | Missense Mutation (SNP) | VAF 301/499 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.586); catalogued as rs778049192; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SNCAIP | c.2191C>T p.R731C | Missense Mutation (SNP) | VAF 172/386 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.732); catalogued as rs755160196, COSV54402033; ClinVar: likely benign; called by muse, mutect2, varscan2
- SPHKAP | c.752G>T p.G251V | Missense Mutation (SNP) | VAF 376/643 reads (58%) | SIFT tolerated (0.1); PolyPhen benign (0.15); catalogued as COSV60885134; called by muse, mutect2, varscan2
- SRPX2 | c.170G>T p.R57L | Missense Mutation (SNP) | VAF 128/654 reads (20%) | SIFT tolerated (0.71); PolyPhen benign (0.048); catalogued as COSV65933759; called by muse, mutect2, varscan2
- STAT6 | c.964C>T p.R322W | Missense Mutation (SNP) | VAF 173/568 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs150956174; called by muse, mutect2, varscan2
- TEX2 | c.85G>A p.V29M | Missense Mutation (SNP) | VAF 398/635 reads (63%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.258); catalogued as rs367869807; called by muse, mutect2, varscan2
- THOC2 | c.2993G>A p.R998H | Missense Mutation (SNP) | VAF 531/685 reads (78%) | SIFT tolerated (0.2); PolyPhen benign (0.009); catalogued as rs1326074013, COSV55547734; called by muse, mutect2, varscan2
- TIMM22 | c.320G>A p.R107H | Missense Mutation (SNP) | VAF 358/582 reads (62%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.493); catalogued as rs998325802; called by muse, mutect2, varscan2
- TMEM175 | c.844G>A p.E282K | Missense Mutation (SNP) | VAF 191/456 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as rs368224007; called by muse, mutect2, varscan2
- TMTC4 | c.695C>T p.A232V (on ENST00000376234 / NM_001350577.2; = p.A251V on NM_032813.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 219/397 reads (55%) | SIFT tolerated (0.09); PolyPhen benign (0.079); catalogued as rs370994636; called by muse, mutect2, varscan2
- TRPV1 | c.277G>A p.G93S | Missense Mutation (SNP) | VAF 107/202 reads (53%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs367865095; called by muse, mutect2, varscan2
- UBR5 | c.6360del p.E2121Kfs*28 | Frame Shift Del (DEL) | VAF 148/708 reads (21%) | catalogued as rs763652408; called by mutect2, varscan2
- UPF3A | c.798del p.E267Rfs*13 | Frame Shift Del (DEL) | VAF 39/319 reads (12%) | catalogued as rs767420916; called by mutect2, varscan2
- UQCRC1 | c.1268G>A p.R423H | Missense Mutation (SNP) | VAF 244/437 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs779551181; called by muse, mutect2, varscan2
- URB2 | c.4484C>T p.P1495L | Missense Mutation (SNP) | VAF 435/760 reads (57%) | SIFT tolerated (0.23); PolyPhen benign (0.011); catalogued as rs761646981; called by muse, mutect2, varscan2
- WDR26 | c.1195C>T p.R399W (on ENST00000414423 / NM_001379403.1; = p.R299W on NM_025160.7) | Missense Mutation (SNP) | VAF 320/541 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1487324984; called by muse, mutect2, varscan2
- ZAN | c.5854G>A p.A1952T | Missense Mutation (SNP) | VAF 96/463 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs767766456; called by muse, mutect2, varscan2
- ZFHX3 | c.766G>A p.V256I | Missense Mutation (SNP) | VAF 147/331 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs764820053, COSV99213393; called by muse, mutect2, varscan2
- ZNF835 | c.176G>A p.R59Q | Missense Mutation (SNP) | VAF 71/176 reads (40%) | SIFT tolerated (0.5); PolyPhen benign (0.017); catalogued as rs1418536699, COSV73379443; called by muse, mutect2, varscan2
- ABCA12 | c.2197G>A p.G733R (on ENST00000272895 / NM_173076.3; = p.G415R on NM_015657.3) | Missense Mutation (SNP) | VAF 60/807 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.929); called by muse, mutect2
- ABCG4 | c.1871G>A p.G624D | Missense Mutation (SNP) | VAF 191/340 reads (56%) | SIFT tolerated (0.21); PolyPhen benign (0.26); called by muse, mutect2, varscan2
- ATRX | c.2518del p.R840Efs*29 | Frame Shift Del (DEL) | VAF 292/672 reads (43%) | called by mutect2, varscan2
- CALY | c.576dup p.G193Rfs*43 | Frame Shift Ins (INS) | VAF 30/137 reads (22%) | called by mutect2, varscan2
- DGKK | c.457C>T p.P153S | Missense Mutation (SNP) | VAF 29/328 reads (9%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- EMILIN1 | c.1322C>A p.A441D | Missense Mutation (SNP) | VAF 15/547 reads (3%) | SIFT tolerated (0.65); PolyPhen benign (0.005); called by muse, mutect2
- ENTPD7 | c.272G>T p.G91V | Missense Mutation (SNP) | VAF 349/572 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FBF1 | c.2571G>T p.E857D (on ENST00000586717; = p.E871D on NM_001319193.1) | Missense Mutation (SNP) | VAF 15/238 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- GUCY1B1 | c.1836G>T p.E612D | Missense Mutation (SNP) | VAF 326/506 reads (64%) | SIFT tolerated (0.4); PolyPhen benign (0.025); called by mutect2, varscan2
- HPX | c.84-8C>T | Splice Region (SNP) | VAF 10/200 reads (5%) | called by muse, mutect2
- INPP5F | c.2480C>G p.S827* | Nonsense Mutation (SNP) | VAF 71/585 reads (12%) | called by muse, mutect2, varscan2
- KDM2A | c.382C>T p.R128C | Missense Mutation (SNP) | VAF 142/363 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- KIAA1109 | c.5036dup p.N1679Kfs*9 | Frame Shift Ins (INS) | VAF 270/563 reads (48%) | called by mutect2, varscan2
- KIAA1614 | c.1900G>A p.G634S | Missense Mutation (SNP) | VAF 24/272 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- KIF11 | c.1136C>T p.T379M | Missense Mutation (SNP) | VAF 308/547 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KRT75 | c.705C>A p.F235L | Missense Mutation (SNP) | VAF 32/646 reads (5%) | SIFT deleterious (0.05); PolyPhen benign (0.097); called by muse, mutect2
- MCM9 | c.3385G>T p.E1129* | Nonsense Mutation (SNP) | VAF 60/807 reads (7%) | called by muse, mutect2
- MIB1 | c.1122G>T p.Q374H | Missense Mutation (SNP) | VAF 40/1079 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.585); called by muse, mutect2
- NPEPPS | c.1999T>A p.S667T | Missense Mutation (SNP) | VAF 44/604 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.243); called by muse, mutect2
- NPTN | c.928G>T p.D310Y | Missense Mutation (SNP) | VAF 219/594 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NPY2R | c.940G>A p.A314T | Missense Mutation (SNP) | VAF 285/494 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PABPN1L | c.94del p.A32Pfs*61 | Frame Shift Del (DEL) | VAF 24/236 reads (10%) | called by mutect2, varscan2
- PLK1 | c.1742G>A p.R581H | Missense Mutation (SNP) | VAF 225/366 reads (61%) | SIFT tolerated (0.15); PolyPhen benign (0.097); called by muse, mutect2, varscan2
- PPM1G | c.1009C>T p.R337* | Nonsense Mutation (SNP) | VAF 253/457 reads (55%) | called by muse, mutect2, varscan2
- SLAIN1 | c.1347T>C p.C449= (on ENST00000466548; = p.C186= on NM_144595.4 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 152/379 reads (40%) | called by muse, mutect2, varscan2
- SRP68 | c.892T>C p.W298R | Missense Mutation (SNP) | VAF 348/658 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); called by muse, varscan2
- TAF15 | c.490C>T p.R164C (on ENST00000605844 / NM_139215.3; = p.R161C on NM_003487.4) | Missense Mutation (SNP) | VAF 42/261 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- TMEM175 | c.1266G>T p.K422N | Missense Mutation (SNP) | VAF 105/228 reads (46%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.532); called by muse, mutect2, varscan2
- TMEM196 | c.204+2T>C p.X68_splice | Splice Site (SNP) | VAF 276/1311 reads (21%) | called by muse, mutect2, varscan2
- WNK3 | c.3748T>C p.Y1250H | Missense Mutation (SNP) | VAF 44/534 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); called by muse, mutect2
- ZBTB44 | c.1292G>A p.R431H | Missense Mutation (SNP) | VAF 222/349 reads (64%) | SIFT tolerated (0.39); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ZNF462 | c.2089G>T p.D697Y | Missense Mutation (SNP) | VAF 74/939 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- ACTRT2 | c.927C>T p.H309= | Silent (SNP) | VAF 132/258 reads (51%) | catalogued as rs762908845, COSV65760724; called by muse, mutect2, varscan2
- BACE2 | c.1188C>T p.F396= | Silent (SNP) | VAF 312/542 reads (58%) | catalogued as rs139156985; called by muse, mutect2, varscan2
- BICRA | c.1224C>T p.N408= | Silent (SNP) | VAF 148/242 reads (61%) | catalogued as rs780989056; called by muse, mutect2, varscan2
- CBX4 | c.1440G>A p.T480= | Silent (SNP) | VAF 188/352 reads (53%) | catalogued as rs1190834202, COSV99490412; called by muse, mutect2, varscan2
- CCSER1 | c.2349T>C p.C783= | Silent (SNP) | VAF 39/749 reads (5%) | called by muse, mutect2
- CDH20 | c.1998C>T p.D666= | Silent (SNP) | VAF 194/712 reads (27%) | catalogued as rs768110003; called by mutect2, varscan2
- CEP95 | c.1347G>A p.S449= | Silent (SNP) | VAF 386/650 reads (59%) | catalogued as rs1236015914; called by muse, mutect2, varscan2
- DCAF15 | c.429C>T p.C143= | Silent (SNP) | VAF 189/328 reads (58%) | catalogued as rs1192465242; called by muse, mutect2, varscan2
- ERAP1 | c.2052T>C p.Y684= | Silent (SNP) | VAF 38/927 reads (4%) | called by muse, mutect2
- GALNT1 | c.231G>A p.E77= | Silent (SNP) | VAF 253/993 reads (25%) | catalogued as rs977114023; called by muse, mutect2, varscan2
- HPS6 | c.1647G>A p.G549= | Silent (SNP) | VAF 110/172 reads (64%) | called by muse, mutect2, varscan2
- HSPG2 | c.1479C>T p.D493= | Silent (SNP) | VAF 232/385 reads (60%) | catalogued as rs774284691, COSV65930883; called by muse, mutect2, varscan2
- IMPG2 | c.3483C>T p.P1161= | Silent (SNP) | VAF 386/672 reads (57%) | catalogued as rs762438976, COSV51985896; called by muse, mutect2, varscan2
- LGI3 | c.1569C>T p.D523= | Silent (SNP) | VAF 177/286 reads (62%) | catalogued as rs996108167, COSV60443592; called by muse, mutect2, varscan2
- MYO3B | c.1992C>T p.G664= | Silent (SNP) | VAF 58/556 reads (10%) | catalogued as rs370958675; called by muse, mutect2, varscan2
- NCKAP5L | c.135G>A p.S45= | Silent (SNP) | VAF 193/615 reads (31%) | catalogued as rs190636882; called by muse, mutect2, varscan2
- NEU4 | c.687C>T p.D229= (on ENST00000391969 / NM_001167602.3; = p.D241= on NM_080741.4) | Silent (SNP) | VAF 140/241 reads (58%) | catalogued as rs759326739; called by muse, mutect2, varscan2
- PDE6A | c.6C>T p.G2= | Silent (SNP) | VAF 99/169 reads (59%) | catalogued as rs745322421, COSV54927243; called by muse, mutect2, varscan2
- PKN1 | c.2379G>A p.T793= | Silent (SNP) | VAF 150/265 reads (57%) | catalogued as rs368511038; called by muse, mutect2, varscan2
- PKP3 | c.45C>T p.A15= | Silent (SNP) | VAF 146/243 reads (60%) | catalogued as rs979999513; called by muse, mutect2, varscan2
- PLEKHG6 | c.2112C>T p.A704= | Silent (SNP) | VAF 175/561 reads (31%) | catalogued as rs201842103; called by muse, mutect2, varscan2
- PLXNB3 | c.1902C>T p.R634= | Silent (SNP) | VAF 108/150 reads (72%) | catalogued as rs369359201, COSV100737014; called by muse, mutect2, varscan2
- PNPLA2 | c.1293C>T p.D431= | Silent (SNP) | VAF 85/182 reads (47%) | catalogued as rs61876745; called by muse, mutect2, varscan2
- PRDM1 | c.1503C>T p.A501= | Silent (SNP) | VAF 151/247 reads (61%) | called by muse, mutect2, varscan2
- PRX | c.3699G>A p.A1233= | Silent (SNP) | VAF 182/328 reads (55%) | catalogued as rs374221477, COSV99396877; called by muse, mutect2, varscan2
- PTPRS | c.2199C>T p.N733= | Silent (SNP) | VAF 79/192 reads (41%) | catalogued as rs1458435351; called by muse, mutect2, varscan2
- RNF169 | c.906G>A p.K302= | Silent (SNP) | VAF 264/474 reads (56%) | called by muse, mutect2, varscan2
- SATB2 | c.804C>T p.N268= | Silent (SNP) | VAF 55/476 reads (12%) | catalogued as rs760068691; called by muse, mutect2, varscan2
- SCN11A | c.4380G>A p.T1460= | Silent (SNP) | VAF 397/667 reads (60%) | catalogued as rs777033605; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SGTA | c.297C>T p.N99= | Silent (SNP) | VAF 102/178 reads (57%) | catalogued as rs756794017; called by muse, mutect2, varscan2
- SLC45A2 | c.228C>A p.L76= | Silent (SNP) | VAF 19/244 reads (8%) | called by muse, mutect2
- SORCS3 | c.3315G>A p.V1105= | Silent (SNP) | VAF 62/586 reads (11%) | called by muse, varscan2
- THSD4 | c.1500G>A p.A500= | Silent (SNP) | VAF 359/605 reads (59%) | catalogued as rs139510947; called by muse, mutect2, varscan2
- TJP2 | c.432C>T p.D144= | Silent (SNP) | VAF 193/390 reads (49%) | catalogued as rs765961360; called by muse, mutect2, varscan2
- TRIP6 | c.726C>T p.H242= | Silent (SNP) | VAF 137/516 reads (27%) | catalogued as rs757138184; called by muse, mutect2, varscan2
- UBR3 | c.1863C>T p.D621= | Silent (SNP) | VAF 84/842 reads (10%) | catalogued as rs552260268, COSV99773456; called by muse, mutect2
- USP9X | c.270G>A p.P90= | Silent (SNP) | VAF 502/688 reads (73%) | catalogued as rs748766605, COSV61075121, COSV61075587; called by muse, mutect2, varscan2
- UTS2R | c.360C>T p.D120= | Silent (SNP) | VAF 51/115 reads (44%) | catalogued as rs199909106, COSV57452570; called by muse, mutect2, varscan2
- ZNF12 | c.1275G>A p.T425= (on ENST00000405858 / NM_016265.4; = p.T387= on NM_006956.3) | Silent (SNP) | VAF 344/962 reads (36%) | catalogued as rs200944240; called by muse, mutect2, varscan2
- ZNF425 | c.1776G>A p.T592= | Silent (SNP) | VAF 226/719 reads (31%) | catalogued as rs1357015530, COSV65200495; called by muse, mutect2, varscan2
- ZNF462 | c.6726G>A p.G2242= | Silent (SNP) | VAF 228/410 reads (56%) | called by muse, mutect2, varscan2
- ZNF735 | c.711A>C p.G237= | Silent (SNP) | VAF 253/1084 reads (23%) | called by muse, mutect2, varscan2
- ZNF865 | c.180C>T p.C60= | Silent (SNP) | VAF 4/42 reads (10%) | catalogued as rs1424534650; called by muse, mutect2
- AC005722.1 | n.836G>A | RNA (SNP) | VAF 71/116 reads (61%) | called by muse, mutect2, varscan2
- AC125421.1 | n.820C>T | RNA (SNP) | VAF 188/363 reads (52%) | catalogued as rs951183230; called by muse, mutect2, varscan2
- ARMCX4 | c.1038+4386G>A | Intron (SNP) | VAF 29/257 reads (11%) | called by muse, mutect2, varscan2
- ATAD2B | c.784+1151C>A | Intron (SNP) | VAF 28/718 reads (4%) | called by muse, mutect2
- ATP1A4 | c.-99G>A | 5'UTR (SNP) | VAF 27/44 reads (61%) | catalogued as rs963295427, COSV63626146; called by muse, mutect2, varscan2
- ATP6V0C | c.-73G>A | 5'UTR (SNP) | VAF 42/62 reads (68%) | catalogued as rs1208729809; called by mutect2, varscan2
- BCLAF3 | c.1951-38G>A | Intron (SNP) | VAF 34/168 reads (20%) | called by muse, mutect2, varscan2
- BOP1 | c.391-57C>T | Intron (SNP) | VAF 99/162 reads (61%) | catalogued as rs1352042391; called by muse, mutect2, varscan2
- BTN3A3 | c.916+9C>T | Intron (SNP) | VAF 90/224 reads (40%) | catalogued as rs771985410; called by muse, mutect2, varscan2
- CACNA1A | c.5644-22G>A | Intron (SNP) | VAF 117/249 reads (47%) | catalogued as rs553597028; called by muse, mutect2, varscan2
- CDH9 | c.999+75del | Intron (DEL) | VAF 46/78 reads (59%) | catalogued as rs768539244; called by mutect2, varscan2
- CELF4 | c.*45-2048G>A | Intron (SNP) | VAF 344/869 reads (40%) | called by muse, mutect2, varscan2
- COL18A1-AS2 | chr21:45405434 G>T | 3'Flank (SNP) | VAF 223/387 reads (58%) | called by muse, mutect2, varscan2
- ELMO3 | c.1421-8dup | Intron (INS) | VAF 36/65 reads (55%) | catalogued as rs776111360; called by mutect2, varscan2
- EP300 | c.2054-10_2054-8del | Intron (DEL) | VAF 160/286 reads (56%) | called by mutect2, varscan2
- FIG4 | c.2376+63C>T | Intron (SNP) | VAF 89/145 reads (61%) | catalogued as rs772043144; called by muse, mutect2, varscan2
- GNA12 | c.526-29212C>A | Intron (SNP) | VAF 171/408 reads (42%) | called by muse, mutect2, varscan2
- GNLY | c.53-292G>A | Intron (SNP) | VAF 25/275 reads (9%) | called by muse, mutect2
- GRIA3 | c.268+18466C>A | Intron (SNP) | VAF 338/447 reads (76%) | called by muse, mutect2, varscan2
- GUF1 | c.-59del | 5'UTR (DEL) | VAF 51/195 reads (26%) | catalogued as rs983557925; called by mutect2, varscan2
- HNF1A | c.1309+53G>A | Intron (SNP) | VAF 45/368 reads (12%) | catalogued as rs753343887; called by muse, mutect2, varscan2
- HNRNPH1 | c.1057+68A>T | Intron (SNP) | VAF 52/135 reads (39%) | called by muse, mutect2, varscan2
- ITPR1 | c.7678-56C>T | Intron (SNP) | VAF 75/128 reads (59%) | catalogued as rs947568591; called by muse, mutect2, varscan2
- LIF | c.*3171del | 3'UTR (DEL) | VAF 20/44 reads (45%) | catalogued as rs1255779883; called by mutect2, varscan2
- MYLK | c.754+30C>T | Intron (SNP) | VAF 103/160 reads (64%) | catalogued as rs373679150; called by muse, mutect2, varscan2
- NDUFV3 | c.170-4662C>T | Intron (SNP) | VAF 180/430 reads (42%) | catalogued as rs1371174417, COSV61088465; called by muse, mutect2
- NME5 | c.-5-42G>A | Intron (SNP) | VAF 14/160 reads (9%) | called by muse, mutect2
- PDCD6 | c.208+86C>T | Intron (SNP) | VAF 29/73 reads (40%) | catalogued as rs1326110915; called by muse, mutect2, varscan2
- PSMD13 | c.569-85dup | Intron (INS) | VAF 18/36 reads (50%) | catalogued as rs374061872; called by mutect2, varscan2
- SCN2A | c.2149+52A>G | Intron (SNP) | VAF 73/116 reads (63%) | called by muse, mutect2, varscan2
- SEPTIN2 | c.-17-59G>A | Intron (SNP) | VAF 145/267 reads (54%) | catalogued as rs953943100; called by muse, mutect2, varscan2
- SHFL | c.644-76C>T | Intron (SNP) | VAF 9/19 reads (47%) | catalogued as rs998260923; called by muse, mutect2, varscan2
- SIN3B | c.*62C>T | 3'UTR (SNP) | VAF 52/97 reads (54%) | catalogued as rs1270859701; called by muse, mutect2, varscan2
- SPDL1 | c.-10dup | 5'UTR (INS) | VAF 149/242 reads (62%) | catalogued as rs766016340; called by mutect2, varscan2
- TBCE | c.472-1122G>A | Intron (SNP) | VAF 201/423 reads (48%) | catalogued as rs748150101; called by muse, mutect2, varscan2
- TMEM143 | c.369+39G>A | Intron (SNP) | VAF 59/104 reads (57%) | catalogued as rs371404057; called by muse, mutect2, varscan2
- TMEM214 | c.1623-86G>A | Intron (SNP) | VAF 21/39 reads (54%) | catalogued as rs1344723023; called by muse, mutect2, varscan2
- XKR8 | c.*6C>T | 3'UTR (SNP) | VAF 188/300 reads (63%) | catalogued as rs774623283; called by muse, mutect2, varscan2
- YIF1A | c.735+21del | Intron (DEL) | VAF 64/176 reads (36%) | catalogued as rs750015700; called by mutect2, varscan2
- ZNF783 | c.802+3337G>A | Intron (SNP) | VAF 67/246 reads (27%) | catalogued as rs779890841; called by muse, mutect2, varscan2
